MMRF case MMRF_1377 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ecc00d90-e5fe-45da-8d32-ba7cad671bd7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.8 years (24,780 days); ISS stage: I; Days to last known disease status: 1,425 days (3.9 years); Days to last follow up: 1,425 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 143 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 165 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 753 days (2.1 years); Days to treatment end: 1,026 days (2.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 753 days (2.1 years); Days to treatment end: 984 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 984 days (2.7 years); Days to treatment end: 1,257 days (3.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,267 days (3.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.4 mg/dL; Beta 2 Microglobulin 0.26 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.82 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 86 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.22 mmol/L.
- Day 179 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Lactate Dehydrogenase 6.72 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 24 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 6.22 mmol/L.
- Day 274 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Beta 2 Microglobulin 0.29 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 6.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 6.27 mmol/L.
- Day 324 (ECOG 1): Hemoglobin 7.32 mmol/L; Leukocytes 5.6 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 7.65 mmol/L.
- Day 444 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Beta 2 Microglobulin 0.23 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 500 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Beta 2 Microglobulin 0.25 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 599 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.74 mg/dL; Beta 2 Microglobulin 0.29 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.94 mmol/L.
- Day 693 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.78 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 0.28 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 6.05 mmol/L.
- Day 784 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.7 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 8.64 mmol/L.
- Day 882 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Beta 2 Microglobulin 0.32 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 10.1 mmol/L.
- Day 954 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Beta 2 Microglobulin 0.25 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 1,046 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 0.2 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 7.04 mmol/L.
- Day 1,148 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Beta 2 Microglobulin 0.21 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.62 mmol/L.
- Day 1,235 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 0.22 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.78 mmol/L.
- Day 1,326 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 8.14 mmol/L.
- Day 1,425 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 7.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -4: Weight: 117 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1377_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1377_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
